Somatic mutation profile of tumor specimen TCGA-49-6742-01A (aliquot TCGA-49-6742-01A-11D-1855-08) from TCGA case TCGA-49-6742, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 70.7 years (25,839 days).
Specimen TCGA-49-6742-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6c61f159-d09f-40db-be0e-69568ad9ff7a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-49-6742-11A (Solid Tissue Normal), aliquot TCGA-49-6742-11A-01D-1855-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/581a1ac5-d35d-4b74-af64-e81dac8b46d9

The open-access MAF lists 296 somatic variants for this specimen: 212 protein-altering or splice-affecting, 79 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 188, Silent 79, Nonsense Mutation 15, Frame Shift Del 4, Splice Region 2, Intron 2, Frame Shift Ins 1, Translation Start Site 1, 5'Flank 1, 3'Flank 1, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.3188C>G p.S1063* | Nonsense Mutation (SNP) | VAF 11/78 reads (14%) | catalogued as COSV64671435; called by muse, mutect2, varscan2
- ABCC11 | c.3959T>A p.I1320N | Missense Mutation (SNP) | VAF 49/156 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62321585; called by muse, mutect2, varscan2
- ABCC5 | c.4215G>A p.V1405= | Splice Region (SNP) | VAF 10/51 reads (20%) | catalogued as COSV55587714; called by muse, mutect2, varscan2
- ACOX2 | c.1543G>T p.V515L | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV57147839; called by muse, mutect2, varscan2
- ADAM7 | c.448G>T p.E150* | Nonsense Mutation (SNP) | VAF 52/167 reads (31%) | catalogued as COSV51535702; called by muse, mutect2, varscan2
- ADAMTS18 | c.344C>T p.S115L | Missense Mutation (SNP) | VAF 42/182 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs145596475, COSV51399037, COSV99273948; called by muse, mutect2, varscan2
- ADGRL3 | c.1196A>T p.D399V (on ENST00000506720 / NM_001322402.2; = p.D331V on NM_015236.6) | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV72266262; called by muse, mutect2, varscan2
- AFP | c.545C>G p.A182G | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV56923903, COSV56924170; called by muse, mutect2, varscan2
- AGXT2 | c.1295G>A p.R432Q | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761319044, COSV51483937; called by muse, mutect2, varscan2
- AHCTF1 | c.971A>G p.Q324R (on ENST00000366508; = p.Q298R on NM_015446.5) | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs774115358, COSV58246423; called by muse, mutect2, varscan2
- ARHGEF17 | c.5421G>C p.Q1807H | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as COSV55230041; called by muse, mutect2, varscan2
- ARHGEF6 | c.1880A>G p.K627R | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.338); catalogued as COSV51687946; called by muse, mutect2, varscan2
- ARSJ | c.830G>T p.R277M | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV59536886, COSV59537108; called by muse, mutect2, varscan2
- ASTN1 | c.3130G>T p.E1044* | Nonsense Mutation (SNP) | VAF 17/129 reads (13%) | catalogued as COSV62492108, COSV62507875; called by muse, mutect2, varscan2
- ATP10B | c.1984G>A p.E662K | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.272); catalogued as rs1375507043, COSV59144263; called by muse, mutect2, varscan2
- ATP11C | c.2039A>C p.K680T | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59560097; called by muse, mutect2
- ATP2B1 | c.3280G>A p.D1094N | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.678); catalogued as rs1465462304, COSV53804504; called by muse, mutect2, varscan2
- ATP8A2 | c.3100A>C p.S1034R | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54939363; called by muse, mutect2, varscan2
- BAG5 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as rs767287868, COSV54570242; called by muse, mutect2, varscan2
- BBS9 | c.2021G>A p.R674Q (on ENST00000242067 / NM_001348036.1; = p.R634Q on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/351 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs555671554, COSV54158185, COSV54192778; called by muse, mutect2
- BCO1 | c.1468C>T p.L490F | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1398682170, COSV50728126; called by muse, mutect2, varscan2
- BRINP3 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 11/47 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as COSV66514824; called by muse, mutect2, varscan2
- CARD11 | c.3409G>A p.D1137N | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs1192612448, COSV67797240; called by muse, mutect2
- CARD9 | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs745942827, COSV53731155; called by mutect2, varscan2
- CASP8AP2 | c.357C>G p.I119M | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52745464; called by muse, mutect2, varscan2
- CCDC25 | c.577G>T p.E193* | Nonsense Mutation (SNP) | VAF 70/236 reads (30%) | catalogued as COSV62958369, COSV62959293; called by muse, mutect2, varscan2
- CCNB3 | c.2620T>G p.F874V | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV52070492; called by muse, mutect2, varscan2
- CDH6 | c.1498G>T p.A500S | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.515); catalogued as COSV54065131, COSV54077032; called by muse, mutect2, varscan2
- CDH8 | c.748G>T p.G250C | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV54851181; called by muse, mutect2, varscan2
- CDK9 | c.914A>C p.D305A | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV64723433; called by muse, mutect2, varscan2
- CELSR3 | c.6553G>A p.E2185K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as COSV50841086; called by muse, mutect2, varscan2
- CENPF | c.8548C>T p.L2850F | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.222); catalogued as COSV65273049, COSV65279713; called by muse, mutect2, varscan2
- CEP76 | c.772C>G p.Q258E | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1568029983, COSV50865611; called by muse, mutect2
- CIITA | c.739G>T p.G247* | Nonsense Mutation (SNP) | VAF 26/74 reads (35%) | catalogued as COSV100161758, COSV60854514; called by muse, mutect2, varscan2
- CNGA2 | c.940G>A p.D314N | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as COSV61703457; called by muse, mutect2, varscan2
- CNPY2 | c.161G>T p.G54V | Missense Mutation (SNP) | VAF 50/146 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56263919; called by muse, mutect2, varscan2
- CNTLN | c.2676G>C p.Q892H | Missense Mutation (SNP) | VAF 56/125 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV52068027; called by muse, mutect2, varscan2
- CTTNBP2 | c.1964C>T p.S655F | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.822); catalogued as COSV50390618, COSV50450085; called by muse, mutect2
- CUBN | c.4888G>A p.D1630N | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.493); catalogued as rs1024232172, COSV64709031; called by muse, mutect2, varscan2
- CYLC2 | c.347A>C p.K116T | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.906); catalogued as COSV66336375, COSV66337337; called by muse, mutect2
- DACT1 | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV60019644; called by muse, varscan2
- DCAF4L1 | c.1160G>A p.R387Q | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1560527443, COSV60786619; called by muse, mutect2, varscan2
- DCLK1 | c.1930C>T p.H644Y | Missense Mutation (SNP) | VAF 58/193 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1213237656, COSV55174392, COSV55204278; called by muse, mutect2, varscan2
- DCLRE1C | c.175C>G p.L59V | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV63182047; called by muse, mutect2, varscan2
- DDI1 | c.507A>C p.E169D | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT tolerated (0.66); PolyPhen benign (0.079); catalogued as COSV56369943; called by muse, mutect2
- DGKI | c.1306G>A p.G436R | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55938452; called by muse, mutect2, varscan2
- DOCK2 | c.760A>C p.S254R | Missense Mutation (SNP) | VAF 9/156 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.13); catalogued as COSV56944625; called by muse, mutect2
- DOCK7 | c.594G>C p.L198F | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51997229, COSV99223371; called by muse, mutect2, varscan2
- DOK2 | c.562G>T p.G188W | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52388890, COSV99374563; called by muse, mutect2, varscan2
- DPEP1 | c.640C>T p.H214Y | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV55359098; called by muse, mutect2, varscan2
- DSC2 | c.1417C>A p.P473T | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51861784; called by muse, mutect2, varscan2
- EMCN | c.761C>G p.S254C | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.171); catalogued as COSV56456966, COSV56459188; called by muse, mutect2, varscan2
- ENOX1 | c.1880C>T p.T627M | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs374338452; called by muse, mutect2, varscan2
- EPHB3 | c.1879G>C p.E627Q | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as COSV57804493; called by muse, mutect2
- ESPN | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.062); catalogued as COSV64703868; called by muse, mutect2, varscan2
- EYA3 | c.10G>C p.E4Q | Missense Mutation (SNP) | VAF 28/268 reads (10%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.069); catalogued as COSV65815620; called by muse, mutect2
- FAM135A | c.4174C>G p.R1392G (on ENST00000370479 / NM_001351599.1; = p.R1179G on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1324325433, COSV52048376; called by muse, mutect2, varscan2
- FCER1A | c.674C>G p.S225* | Nonsense Mutation (SNP) | VAF 30/112 reads (27%) | catalogued as COSV63666616; called by muse, mutect2, varscan2
- FNDC3A | c.1561G>C p.E521Q (on ENST00000492622 / NM_001079673.2; = p.E465Q on NM_014923.5) | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as COSV68132405; called by muse, mutect2, varscan2
- FUCA1 | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV65692336; called by muse, mutect2, varscan2
- GABRG2 | c.1386A>C p.E462D (on ENST00000361925 / NM_001375343.1; = p.E422D on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/195 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.992); catalogued as COSV62715785; called by muse, mutect2, varscan2
- GFRAL | c.998G>C p.R333T | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as COSV61229072; called by muse, mutect2, varscan2
- GJD2 | c.747G>C p.E249D | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51747294, COSV99290692; called by muse, mutect2, varscan2
- GLP2R | c.1412T>G p.F471C | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.525); catalogued as COSV52322570; called by muse, mutect2, varscan2
- GPC3 | c.302A>G p.K101R | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV63659768; called by muse, mutect2, varscan2
- GRIA1 | c.22T>C p.F8L | Missense Mutation (SNP) | VAF 14/429 reads (3%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV53590838; called by muse, mutect2
- GRK1 | c.410G>A p.G137E | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV59554100; called by muse, mutect2
- GRM1 | c.2560G>A p.D854N | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.996); catalogued as COSV51110977; called by muse, mutect2, varscan2
- HOXB3 | c.251C>T p.S84L | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs879013282, COSV61142750; called by muse, mutect2, varscan2
- HOXD3 | c.223C>A p.P75T | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV50879152; called by muse, mutect2, varscan2
- IFT88 | c.2467G>C p.D823H (on ENST00000319980 / NM_001318493.2; = p.D814H on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60671684; called by muse, mutect2, varscan2
- IGFL2 | c.79G>T p.A27S (on ENST00000377693 / NM_001135113.2; = p.A38S on NM_001002915.2) | Missense Mutation (SNP) | VAF 83/174 reads (48%) | SIFT tolerated (0.49); PolyPhen benign (0.067); catalogued as COSV66616652; called by muse, mutect2, varscan2
- IKZF1 | c.706C>G p.L236V | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100498880, COSV58781801; called by muse, mutect2, varscan2
- IP6K2 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as COSV53659935; called by muse, mutect2, varscan2
- KEAP1 | c.803T>C p.L268P | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV50263220; called by muse, mutect2, varscan2
- KHDRBS3 | c.227T>G p.L76R | Missense Mutation (SNP) | VAF 10/137 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100879073, COSV63415230; called by muse, mutect2
- KLF6 | c.800G>T p.R267M | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51493861; called by muse, mutect2, varscan2
- KRTAP10-6 | c.893G>T p.C298F | Missense Mutation (SNP) | VAF 63/150 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100552903; called by muse, mutect2, varscan2
- LACTB2 | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 56/342 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as rs1425561038, COSV52567052; called by muse, mutect2, varscan2
- LARP4B | c.1012G>A p.A338T | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV60220193; called by muse, mutect2
- LEFTY2 | c.978G>T p.M326I | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.075); catalogued as COSV64746452; called by muse, mutect2, varscan2
- LNPK | c.1232G>T p.G411V | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV55822574, COSV55822590; called by muse, mutect2, varscan2
- LRP1B | c.12421C>G p.Q4141E | Missense Mutation (SNP) | VAF 32/177 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV67191564, COSV67214099; called by muse, mutect2, varscan2
- LRRC40 | c.1738C>A p.P580T | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63941662, COSV63941746; called by muse, mutect2
- LRRK1 | c.3746G>A p.G1249D | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52603389, COSV52622715; called by muse, mutect2, varscan2
- LRRN1 | c.1745A>C p.N582T | Missense Mutation (SNP) | VAF 35/325 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60012620; called by muse, mutect2, varscan2
- MARCHF4 | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated, low confidence (0.44); PolyPhen probably damaging (0.946); catalogued as COSV56103197; called by muse, mutect2, varscan2
- MCTP2 | c.619G>T p.V207F | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762438951, COSV59141377; called by muse, mutect2, varscan2
- MDC1 | c.4600G>T p.A1534S | Missense Mutation (SNP) | VAF 68/385 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.404); catalogued as COSV64523484; called by muse, mutect2, varscan2
- MITF | c.560A>C p.N187T (on ENST00000448226 / NM_006722.3; = p.N81T on NM_000248.4) | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.099); catalogued as COSV58830072; called by muse, mutect2, varscan2
- MROH9 | c.421A>G p.R141G | Missense Mutation (SNP) | VAF 35/205 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1463857381, COSV63010191; called by muse, mutect2, varscan2
- MTMR11 | c.1859C>T p.P620L (on ENST00000439741 / NM_001145862.2; = p.P548L on NM_181873.3) | Missense Mutation (SNP) | VAF 35/209 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.035); catalogued as COSV54964477; called by muse, mutect2, varscan2
- MTR | c.3394C>T p.R1132W | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201991154, COSV63963993; called by muse, mutect2
- MUC7 | c.559G>C p.E187Q | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.052); catalogued as COSV59217221, COSV59219741; called by muse, varscan2
- MX2 | c.166G>T p.A56S | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV58095329; called by muse, mutect2, varscan2
- MYCL | c.1034G>C p.R345T | Missense Mutation (SNP) | VAF 63/169 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV65693232; called by muse, mutect2, varscan2
- MYEF2 | c.998G>T p.G333V | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99981440; called by muse, mutect2
- MYOZ1 | c.808C>G p.R270G | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV63771596; called by muse, mutect2, varscan2
- NAV2 | c.2400G>T p.R800S (on ENST00000396087 / NM_001244963.2; = p.R777S on NM_145117.5) | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV62316422; called by muse, mutect2, varscan2
- NDST3 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV56613808; called by muse, mutect2, varscan2
- NEK10 | c.3500A>G p.N1167S | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.007); catalogued as rs1389176023, COSV55354917; called by muse, mutect2
- NLGN4X | c.1036G>T p.G346C | Missense Mutation (SNP) | VAF 42/65 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52006420, COSV52017167; called by muse, mutect2, varscan2
- NOP53 | c.745C>G p.P249A | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99884266; called by muse, mutect2, varscan2
- OARD1 | c.332G>A p.G111E | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.929); catalogued as COSV55107396, COSV55107660; called by muse, mutect2, varscan2
- OR10R2 | c.358C>T p.Q120* | Nonsense Mutation (SNP) | VAF 128/522 reads (25%) | catalogued as rs759019928, COSV63768522; called by muse, mutect2, varscan2
- OR2D2 | c.472G>T p.V158L | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.083); catalogued as COSV55056509; called by muse, mutect2, varscan2
- OR2M4 | c.52T>G p.F18V | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); catalogued as COSV60707391; called by muse, mutect2
- OR51A4 | c.699G>T p.K233N | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV66749118, COSV66749413; called by muse, mutect2, varscan2
- OR52R1 | c.481C>A p.P161T | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61887585; called by muse, mutect2, varscan2
- OR5I1 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.223); catalogued as COSV100041348; called by muse, mutect2, varscan2
- OR5L2 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 97/296 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1414105013, COSV65723466; called by muse, mutect2, varscan2
- OR8J3 | c.349G>T p.V117L | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV56879572; called by muse, mutect2, varscan2
- OSBPL8 | c.2163A>T p.K721N | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.954); catalogued as COSV53878876; called by muse, mutect2, varscan2
- OVCH1 | c.2047G>T p.V683L | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV58960132; called by muse, mutect2, varscan2
- PACSIN1 | c.429G>C p.Q143H | Missense Mutation (SNP) | VAF 49/86 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV55058796; called by muse, mutect2, varscan2
- PAPPA | c.417G>A p.G139= | Splice Region (SNP) | VAF 11/76 reads (14%) | catalogued as rs138083509; called by muse, mutect2, varscan2
- PARD3B | c.540G>C p.L180F | Missense Mutation (SNP) | VAF 40/168 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV62504124, COSV62523384; called by muse, mutect2, varscan2
- PARD3B | c.1621G>A p.D541N | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1324926613, COSV62504135; called by muse, mutect2, varscan2
- PCDHA11 | c.1133C>T p.S378L | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.367); catalogued as COSV56481009; called by muse, mutect2, varscan2
- PCDHGA2 | c.1206C>A p.Y402* | Nonsense Mutation (SNP) | VAF 36/95 reads (38%) | catalogued as rs1459415373, COSV53906911; called by muse, mutect2, varscan2
- PHF14 | c.1342C>T p.R448C | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1381854007, COSV68854352; called by muse, mutect2, varscan2
- PLA2G4D | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.105); catalogued as COSV51819412; called by muse, mutect2
- PLA2R1 | c.1078C>T p.H360Y | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.177); catalogued as COSV51775480; called by muse, mutect2
- POLG | c.3117G>C p.K1039N | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.534); catalogued as COSV51519951; called by muse, varscan2
- POLR3C | c.884G>A p.R295K | Missense Mutation (SNP) | VAF 44/195 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.093); catalogued as COSV61936112; called by muse, mutect2, varscan2
- PPARG | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV55140955; called by muse, mutect2, varscan2
- PPARGC1B | c.1726C>A p.L576M | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV58526709; called by muse, mutect2
- PPP3CC | c.587G>A p.G196E | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV51499618; called by muse, mutect2
- PRKDC | c.3830G>C p.G1277A | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV58044856; called by muse, mutect2, varscan2
- PRSS55 | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 91/350 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.091); catalogued as COSV60807834; called by muse, mutect2, varscan2
- PSG7 | c.1124C>G p.S375* | Nonsense Mutation (SNP) | VAF 110/378 reads (29%) | catalogued as COSV68444400; called by muse, mutect2, varscan2
- PTCH1 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV59464695; called by muse, mutect2, varscan2
- PXDNL | c.2262G>T p.Q754H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV62480008; called by muse, mutect2
- RAPGEF2 | c.2870G>T p.R957L | Missense Mutation (SNP) | VAF 102/217 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as COSV100030446, COSV52425269; called by muse, mutect2, varscan2
- RBBP6 | c.3922G>T p.E1308* | Nonsense Mutation (SNP) | VAF 6/59 reads (10%) | catalogued as COSV60503598; called by muse, mutect2, varscan2
- RBM19 | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV55688694; called by muse, mutect2, varscan2
- RBM45 | c.378G>A p.M126I | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.322); catalogued as COSV53720117; called by muse, mutect2, varscan2
- RFX5 | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 74/291 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.243); catalogued as COSV51838136; called by muse, mutect2, varscan2
- RGS6 | c.831G>C p.L277F | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as COSV59566429; called by muse, mutect2, varscan2
- RILP | c.665C>G p.P222R | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.322); catalogued as rs1283043019; called by muse, mutect2
- RIT2 | c.632A>C p.K211T | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.354); catalogued as COSV100452099, COSV58660667; called by muse, mutect2, varscan2
- RNASE10 | c.135G>T p.W45C | Missense Mutation (SNP) | VAF 65/156 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV100116065, COSV60517425; called by muse, mutect2, varscan2
- RNF121 | c.526A>G p.M176V | Missense Mutation (SNP) | VAF 55/177 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.214); catalogued as rs1382221636, COSV62316107; called by muse, mutect2, varscan2
- RNF213 | c.9343G>A p.A3115T | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs746145556, COSV60391566; called by muse, mutect2, varscan2
- RPL5 | c.712G>T p.E238* | Nonsense Mutation (SNP) | VAF 37/148 reads (25%) | catalogued as COSV59872916; called by muse, mutect2, varscan2
- RSRP1 | c.344C>G p.S115C | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54562227; called by muse, mutect2, varscan2
- RYR2 | c.7239G>C p.K2413N | Missense Mutation (SNP) | VAF 71/327 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63665928, COSV63700760; called by muse, mutect2, varscan2
- SAFB | c.1269G>C p.K423N | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV52649918; called by muse, mutect2, varscan2
- SCCPDH | c.739C>G p.P247A | Missense Mutation (SNP) | VAF 46/234 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV100829739, COSV63618123; called by muse, mutect2, varscan2
- SCN3A | c.5138G>T p.G1713V | Missense Mutation (SNP) | VAF 79/259 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV51802739; called by muse, mutect2, varscan2
- SELE | c.1171G>C p.G391R | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.096); catalogued as COSV60974160; called by muse, mutect2, varscan2
- SLC25A39 | c.515G>T p.R172L (on ENST00000377095 / NM_001143780.3; = p.R164L on NM_016016.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56586523; called by muse, mutect2, varscan2
- SLC26A7 | c.1517C>T p.S506L | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.666); catalogued as COSV52587192; called by muse, mutect2, varscan2
- SMARCA4 | c.4477G>T p.E1493* | Nonsense Mutation (SNP) | VAF 16/34 reads (47%) | catalogued as COSV60788201; called by muse, mutect2, varscan2
- SNRNP200 | c.5383G>T p.D1795Y | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as COSV60487670; called by muse, mutect2, varscan2
- SPATA18 | c.401A>C p.Q134P | Missense Mutation (SNP) | VAF 5/154 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV54642112; called by muse, mutect2
- SPEF2 | c.3910G>T p.E1304* | Nonsense Mutation (SNP) | VAF 17/70 reads (24%) | catalogued as COSV61544772, COSV61548574; called by muse, mutect2, varscan2
- SPTA1 | c.5810C>A p.A1937D | Missense Mutation (SNP) | VAF 15/328 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63749641, COSV63750596; called by muse, mutect2
- STK31 | c.2651C>T p.S884L | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.37); catalogued as rs759136544, COSV100669925, COSV63454386; called by muse, mutect2
- STYXL2 | c.2929A>G p.S977G | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as COSV54802537; called by muse, mutect2, varscan2
- SUN3 | c.793G>C p.E265Q | Missense Mutation (SNP) | VAF 28/234 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); catalogued as COSV52048855; called by muse, mutect2, varscan2
- SUN3 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV52048888, COSV99813780; called by muse, mutect2, varscan2
- SYCP1 | c.1696C>G p.Q566E | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764741383, COSV65694912; called by muse, mutect2, varscan2
- SYMPK | c.3670G>C p.E1224Q | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.962); catalogued as COSV55570271; called by muse, mutect2, varscan2
- SYNJ1 | c.2553G>T p.R851S | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV59144857; called by muse, mutect2, varscan2
- TELO2 | c.1888G>T p.G630W | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.523); catalogued as COSV51976264, COSV51982004; called by muse, mutect2, varscan2
- TERB2 | c.548A>G p.K183R | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.201); catalogued as rs1389788484; called by muse, mutect2, varscan2
- TESC | c.92G>T p.R31I | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58810976; called by muse, mutect2, varscan2
- TEX15 | c.1891G>A p.E631K (on ENST00000256246; = p.E1014K on NM_001350162.2) | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV56342375; called by muse, mutect2, varscan2
- TFDP3 | c.332T>A p.L111Q | Missense Mutation (SNP) | VAF 73/111 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59536041; called by muse, mutect2, varscan2
- THADA | c.4866G>C p.Q1622H | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV57677069; called by muse, mutect2, varscan2
- THBS4 | c.2848G>A p.E950K | Missense Mutation (SNP) | VAF 43/191 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0.339); catalogued as rs1473318179, COSV63467908; called by muse, mutect2, varscan2
- TLR4 | c.1840G>A p.D614N (on ENST00000355622 / NM_138554.5; = p.D574N on NM_003266.4) | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV62922540; called by muse, mutect2, varscan2
- TLR4 | c.2342A>G p.Q781R (on ENST00000355622 / NM_138554.5; = p.Q741R on NM_003266.4) | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.398); catalogued as rs759150917, COSV62922544; called by mutect2, varscan2
- TM7SF3 | c.1432G>A p.V478M | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs756132461, COSV58001509; called by muse, mutect2, varscan2
- TRAM2 | c.767G>T p.R256L | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); catalogued as COSV51731769, COSV51732192; called by muse, mutect2, varscan2
- TRO | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV51498209; called by muse, mutect2, varscan2
- TRPS1 | c.2060G>A p.R687K (on ENST00000220888 / NM_001330599.2; = p.R700K on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.754); catalogued as COSV55228412; called by muse, mutect2, varscan2
- TSPAN19 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.422); catalogued as COSV70813422; called by muse, mutect2, varscan2
- TUBA1A | c.1321G>C p.E441Q | Missense Mutation (SNP) | VAF 12/291 reads (4%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.214); catalogued as COSV55496938; called by muse, mutect2
- TUBA4A | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.751); catalogued as rs147946711, COSV50277753; called by muse, mutect2, varscan2
- USH2A | c.3832C>G p.L1278V | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.67); catalogued as COSV56333840; called by muse, mutect2, varscan2
- USP44 | c.515G>A p.G172E | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.703); catalogued as COSV51562264; called by muse, mutect2, varscan2
- USP53 | c.2655C>G p.I885M | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV56792668; called by muse, mutect2, varscan2
- USPL1 | c.2096A>T p.D699V | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); catalogued as COSV54998849; called by muse, mutect2, varscan2
- VCAM1 | c.179G>A p.R60K | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54118015; called by muse, mutect2, varscan2
- VWA2 | c.1181C>T p.A394V | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs780975574, COSV53905192; called by muse, mutect2
- WFS1 | c.809A>T p.D270V | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.44); catalogued as COSV56987683, COSV56991444; called by muse, mutect2, varscan2
- XIRP2 | c.439G>A p.E147K (on ENST00000628543; = p.E322K on NM_152381.6) | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV54685334; called by muse, mutect2, varscan2
- XYLB | c.173G>C p.G58A | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV52911779; called by muse, mutect2, varscan2
- YTHDF2 | c.1121C>T p.S374F | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV65722822; called by muse, mutect2, varscan2
- ZNF283 | c.1244G>T p.G415V | Missense Mutation (SNP) | VAF 47/156 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.075); catalogued as COSV61030506; called by muse, mutect2, varscan2
- ZNF521 | c.1853A>C p.K618T | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV64123091; called by muse, mutect2, varscan2
- ZNF532 | c.3379G>T p.E1127* | Nonsense Mutation (SNP) | VAF 33/79 reads (42%) | catalogued as COSV60172014; called by muse, mutect2, varscan2
- ZNF804A | c.2314C>T p.R772C | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs762537446, COSV56437409; called by muse, mutect2, varscan2
- BARD1 | c.575C>T p.S192F | Missense Mutation (SNP) | VAF 46/169 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CCND1 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2, varscan2
- CUBN | c.584del p.G195Efs*39 | Frame Shift Del (DEL) | VAF 9/44 reads (20%) | called by mutect2, pindel, varscan2
- DOK2 | c.563G>A p.G188E | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- DUSP19 | c.98A>G p.E33G | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- EPN2 | c.1038del p.A347Rfs*104 | Frame Shift Del (DEL) | VAF 31/130 reads (24%) | called by mutect2, pindel, varscan2
- FRYL | c.4433C>G p.S1478* | Nonsense Mutation (SNP) | VAF 5/54 reads (9%) | called by muse, mutect2
- FSCN3 | c.257del p.R86Pfs*25 | Frame Shift Del (DEL) | VAF 19/54 reads (35%) | called by mutect2, pindel, varscan2
- MRPL37 | c.332delinsTT p.C111Ffs*28 | Frame Shift Ins (INS) | VAF 17/71 reads (24%) | called by pindel, varscan2*
- NFIC | c.815_819del p.P272Hfs*36 | Frame Shift Del (DEL) | VAF 25/49 reads (51%) | called by mutect2, pindel, varscan2
- NPL | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PACS2 | c.124_132del p.C42_L44del | In Frame Del (DEL) | VAF 13/88 reads (15%) | called by mutect2, pindel, varscan2
- PRAMEF17 | c.1120A>C p.S374R | Missense Mutation (SNP) | VAF 28/292 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); called by muse, mutect2
- RBM14 | c.530G>A p.G177E | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- SKP1 | c.139C>G p.L47V | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- SLC7A5 | c.1470C>G p.F490L | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT tolerated (0.73); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZP3 | c.405G>C p.E135D (on ENST00000394857 / NM_001110354.2; = p.E84D on NM_007155.6) | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.48); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ABCC5 | c.1743C>T p.I581= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as rs762477749, COSV55591528; called by mutect2, varscan2
- ADAMTS6 | c.966C>T p.L322= | Silent (SNP) | VAF 29/82 reads (35%) | catalogued as rs1386320396, COSV66857297; called by muse, mutect2, varscan2
- ADD2 | c.18C>A p.V6= | Silent (SNP) | VAF 29/113 reads (26%) | catalogued as COSV52455668; called by muse, mutect2, varscan2
- AGAP3 | c.1017C>T p.F339= (on ENST00000622464; = p.F375= on NM_031946.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs1185738175; called by muse, mutect2, varscan2
- AMPD2 | c.2022C>T p.I674= | Silent (SNP) | VAF 71/212 reads (33%) | catalogued as rs1172113964, COSV56646373; called by muse, mutect2, varscan2
- AQP1 | c.645G>A p.G215= | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as rs1444358457, COSV61266194; called by muse, mutect2, varscan2
- AR | c.1641T>G p.V547= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as COSV65953535; called by muse, mutect2, varscan2
- ARMC7 | c.501C>T p.F167= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV99822745; called by muse, mutect2
- ATP8A2 | c.105G>A p.K35= | Silent (SNP) | VAF 9/95 reads (9%) | catalogued as COSV54939353, COSV99679341; called by muse, mutect2, varscan2
- BAG1 | c.345G>A p.E115= | Silent (SNP) | VAF 28/45 reads (62%) | called by muse, mutect2, varscan2
- CACNA1I | c.372C>T p.I124= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as rs1402532663, COSV60802150; called by muse, mutect2, varscan2
- CCDC60 | c.219G>C p.L73= | Silent (SNP) | VAF 54/168 reads (32%) | catalogued as COSV100554678, COSV59540716; called by muse, mutect2, varscan2
- CCND1 | c.513G>T p.A171= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as COSV99919648; called by muse, mutect2, varscan2
- CD1A | c.465G>T p.G155= | Silent (SNP) | VAF 34/132 reads (26%) | catalogued as rs1290836529, COSV56860486; called by muse, varscan2
- CEP170 | c.3945G>A p.E1315= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs1455922347, COSV100316887; called by mutect2, varscan2
- CHD6 | c.7203G>C p.L2401= | Silent (SNP) | VAF 22/104 reads (21%) | catalogued as COSV64688632, COSV64691910; called by muse, mutect2, varscan2
- CISD2 | c.180C>T p.L60= | Silent (SNP) | VAF 24/125 reads (19%) | catalogued as COSV56765526; called by muse, mutect2, varscan2
- CLASRP | c.1095C>T p.P365= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs774089594, COSV55514660, COSV55517471; called by muse, mutect2, varscan2
- COL4A5 | c.1656T>G p.T552= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV60356102; called by muse, mutect2, varscan2
- DLGAP2 | c.1005C>T p.F335= | Silent (SNP) | VAF 36/132 reads (27%) | catalogued as rs777660875, COSV70094830; called by muse, mutect2, varscan2
- DNAL1 | c.345G>A p.K115= | Silent (SNP) | VAF 17/52 reads (33%) | called by muse, mutect2, varscan2
- DNMT1 | c.498C>T p.T166= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV61576894; called by muse, mutect2, varscan2
- DOCK2 | c.5409C>A p.V1803= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as COSV56944632; called by muse, mutect2, varscan2
- DPH1 | c.96C>T p.I32= | Silent (SNP) | VAF 27/102 reads (26%) | catalogued as COSV53983828, COSV53986200; called by muse, mutect2, varscan2
- DRC7 | c.2553G>T p.L851= | Silent (SNP) | VAF 27/78 reads (35%) | catalogued as COSV61053280; called by muse, mutect2, varscan2
- EIF2B3 | c.771G>A p.E257= | Silent (SNP) | VAF 71/256 reads (28%) | catalogued as COSV64516891; called by muse, mutect2, varscan2
- FZD7 | c.87C>T p.G29= | Silent (SNP) | VAF 28/67 reads (42%) | catalogued as rs1236286070; called by muse, mutect2, varscan2
- GCNT4 | c.96A>G p.L32= | Silent (SNP) | VAF 68/306 reads (22%) | catalogued as COSV59280501; called by muse, mutect2, varscan2
- GK | c.1425C>T p.V475= (on ENST00000427190 / NM_001205019.2; = p.V469= on NM_000167.6) | Silent (SNP) | VAF 15/25 reads (60%) | catalogued as COSV66732075; called by muse, mutect2, varscan2
- GOLGA3 | c.3919C>T p.L1307= | Silent (SNP) | VAF 46/125 reads (37%) | catalogued as COSV52626366; called by muse, mutect2, varscan2
- GUCY1A2 | c.2133T>G p.S711= | Silent (SNP) | VAF 16/244 reads (7%) | catalogued as COSV56479289; called by muse, mutect2
- HIC2 | c.1626C>T p.F542= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as COSV68041758; called by muse, mutect2, varscan2
- IFT81 | c.1290G>A p.R430= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV54360863; called by muse, mutect2, varscan2
- IRGC | c.810C>T p.T270= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as rs926507114, COSV54983035, COSV54986584; called by muse, mutect2, varscan2
- KCTD8 | c.723C>T p.I241= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as rs1316891381, COSV63585841, COSV63593698; called by muse, mutect2
- KIF2B | c.1212G>T p.V404= | Silent (SNP) | VAF 28/91 reads (31%) | catalogued as COSV52127507; called by muse, mutect2, varscan2
- LAMA3 | c.9306C>T p.I3102= (on ENST00000313654 / NM_198129.4; = p.I1493= on NM_000227.6) | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as COSV52530590; called by muse, mutect2, varscan2
- LDLRAD3 | c.249T>C p.H83= | Silent (SNP) | VAF 8/132 reads (6%) | catalogued as COSV59679016; called by muse, mutect2
- LHFPL5 | c.213C>T p.N71= | Silent (SNP) | VAF 39/228 reads (17%) | catalogued as COSV64177644; called by muse, mutect2, varscan2
- LY75 | c.5103C>T p.F1701= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as COSV55102517; called by muse, mutect2, varscan2
- MCM3AP | c.5214G>A p.E1738= | Silent (SNP) | VAF 8/124 reads (6%) | catalogued as COSV52436712; called by muse, mutect2
- MNDA | c.766T>C p.L256= | Silent (SNP) | VAF 6/71 reads (8%) | catalogued as COSV63740041; called by muse, mutect2
- MYEF2 | c.999C>T p.G333= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs1270397776, COSV99981437; called by muse, mutect2, varscan2
- NEFM | c.72C>T p.F24= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV99647164; called by muse, varscan2
- NME1-NME2 | c.570G>A p.Q190= (on ENST00000555572; = p.Q165= on NM_001018136.3) | Silent (SNP) | VAF 7/132 reads (5%) | called by muse, mutect2
- NUMA1 | c.1507C>T p.L503= | Silent (SNP) | VAF 18/138 reads (13%) | catalogued as rs1203671678, COSV61183613; called by muse, mutect2, varscan2
- OR1C1 | c.549T>C p.P183= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as rs1291669078, COSV68715437; called by muse, mutect2, varscan2
- OR2T10 | c.594C>T p.F198= | Silent (SNP) | VAF 20/117 reads (17%) | catalogued as rs776431345, COSV57896221; called by muse, mutect2, varscan2
- OR2T2 | c.660G>A p.T220= | Silent (SNP) | VAF 30/45 reads (67%) | catalogued as rs770828092, COSV61617719; called by mutect2, varscan2
- OR5C1 | c.93C>T p.L31= | Silent (SNP) | VAF 28/87 reads (32%) | catalogued as rs949063630, COSV65455908; called by muse, mutect2, varscan2
- OR5T1 | c.600T>A p.S200= | Silent (SNP) | VAF 21/298 reads (7%) | catalogued as COSV100478902, COSV57301674, COSV57301917; called by muse, mutect2
- PIEZO2 | c.6996C>G p.L2332= | Silent (SNP) | VAF 50/133 reads (38%) | catalogued as COSV53286859; called by muse, mutect2, varscan2
- PNMA8A | c.861G>A p.P287= | Silent (SNP) | VAF 78/148 reads (53%) | catalogued as rs377335947; called by mutect2, varscan2
- PNMA8A | c.237G>C p.L79= | Silent (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2, varscan2
- POLQ | c.1479C>T p.I493= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV51746912, COSV51755159; called by muse, mutect2, varscan2
- POTEF | c.420G>A p.L140= | Silent (SNP) | VAF 37/168 reads (22%) | catalogued as COSV62540009; called by muse, varscan2
- PRKCB | c.18G>T p.A6= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV57768259, COSV57769926; called by muse, varscan2
- PRRX1 | c.513C>T p.D171= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as rs374262561; called by muse, mutect2, varscan2
- PTCD1 | c.1461C>T p.I487= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as COSV52861239, COSV52865470; called by muse, mutect2, varscan2
- PTH2R | c.1236C>T p.I412= | Silent (SNP) | VAF 71/194 reads (37%) | catalogued as COSV55914255; called by muse, mutect2, varscan2
- SAMD9L | c.2784C>T p.L928= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as COSV100560837, COSV59079947; called by muse, mutect2, varscan2
- SDS | c.792C>A p.I264= | Silent (SNP) | VAF 40/117 reads (34%) | catalogued as COSV55105648; called by muse, mutect2, varscan2
- SHROOM3 | c.1530G>A p.K510= | Silent (SNP) | VAF 17/132 reads (13%) | catalogued as COSV56024099; called by muse, mutect2, varscan2
- SLC15A3 | c.765C>G p.P255= | Silent (SNP) | VAF 25/87 reads (29%) | catalogued as COSV57170958; called by muse, mutect2, varscan2
- SLC22A18 | c.204C>T p.F68= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as COSV56539084; called by muse, mutect2, varscan2
- SLC8A1 | c.1692T>C p.S564= | Silent (SNP) | VAF 12/247 reads (5%) | catalogued as COSV60472486; called by muse, mutect2
- SLC9C2 | c.3327C>T p.V1109= | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as rs538975028, COSV62944181; called by muse, mutect2, varscan2
- SMPD3 | c.501C>A p.I167= | Silent (SNP) | VAF 5/70 reads (7%) | catalogued as COSV54710721; called by muse, mutect2
- SUPT6H | c.1530G>A p.Q510= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV58924957; called by muse, mutect2
- TBC1D32 | c.3681G>A p.V1227= | Silent (SNP) | VAF 36/86 reads (42%) | catalogued as rs765491970, COSV51537677; called by muse, mutect2, varscan2
- TENM2 | c.1062G>A p.R354= (on ENST00000518659 / NM_001122679.2; = p.R163= on NM_001080428.3) | Silent (SNP) | VAF 17/92 reads (18%) | catalogued as rs1349088037, COSV69123747; called by muse, mutect2, varscan2
- THAP7 | c.879G>A p.L293= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV53149359; called by muse, mutect2, varscan2
- TRPV5 | c.732C>T p.F244= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV54683264; called by mutect2, varscan2
- TTN | c.25407T>G p.S8469= (on ENST00000591111; = p.S7542= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/100 reads (11%) | catalogued as rs1382315455, COSV59870414; called by muse, mutect2
- USP28 | c.2541G>T p.L847= | Silent (SNP) | VAF 26/83 reads (31%) | catalogued as COSV50156290; called by muse, mutect2, varscan2
- ZBED4 | c.255G>A p.A85= | Silent (SNP) | VAF 23/142 reads (16%) | catalogued as rs567666505, COSV53464017; called by muse, mutect2, varscan2
- ZBTB12 | c.147C>T p.V49= | Silent (SNP) | VAF 6/41 reads (15%) | called by muse, mutect2, varscan2
- ZNF35 | c.1290C>T p.L430= | Silent (SNP) | VAF 20/99 reads (20%) | catalogued as rs1198399164, COSV56075953; called by muse, mutect2, varscan2
- ZNF721 | c.822T>C p.F274= (on ENST00000338977; = p.F286= on NM_133474.4) | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as COSV59089742; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65506042 G>A | 5'Flank (SNP) | VAF 26/79 reads (33%) | called by muse, mutect2, varscan2
- DNAAF5 | c.1784-1314G>A | Intron (SNP) | VAF 7/24 reads (29%) | catalogued as rs1023085536; called by muse, mutect2, varscan2
- HUWE1 | c.1490-600G>T | Intron (SNP) | VAF 5/8 reads (63%) | called by muse, mutect2, varscan2
- NEK5 | c.-1C>T | 5'UTR (SNP) | VAF 32/220 reads (15%) | catalogued as COSV100839204; called by muse, mutect2, varscan2
- RN7SL176P | chr12:100158044 G>A | 3'Flank (SNP) | VAF 9/46 reads (20%) | catalogued as rs1488956813; called by muse, mutect2, varscan2
